CPTAC case C3L-07019 — Hematopoietic and reticuloendothelial systems — Myeloid Leukemias (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1dc55aee-9c92-44c4-a9e4-36aa1b0f9a4f

Demographics
Sex at birth: male; Race: white; Year of birth: 1983; Vital status: Alive; Country of birth: Russia.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Bone marrow; Age at diagnosis: 38.3 years (13,982 days); Year of diagnosis: 2021; Days to last known disease status: 8 days; Progression or recurrence: no; Days to last follow up: 8 days.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (1 entry)
- Days to follow up: 8 days; Karnofsky performance status: 60; ECOG performance status: 2.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 9; Cigarettes per day: 10; Tobacco smoking onset year: 2003; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 19.

Biospecimens (6 samples)
- Samples C3L-07019-50, C3L-07019-51, C3L-07019-52, C3L-07019-53 (4 with the same recorded description): Sample type: Buccal Cell Normal; Tissue type: Normal; Specimen type: Buccal Cells; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC).
- Samples C3L-07019-55, C3L-07019-56 (2 with the same recorded description): Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC); Days to sample procurement: 6 days; Method of sample procurement: Bone Marrow Aspirate; Diagnosis pathologically confirmed: Yes.
